Somatic mutation profile of tumor specimen 0c87932d-b6fd-4eb5-b86a-a34d07 (aliquot 0c87932d-b6fd-4eb5-b86a-a34d07_D6_1) from CPTAC case 02OV032, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 0c87932d-b6fd-4eb5-b86a-a34d07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d667300-433a-4405-9fbf-1defe5cd094f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 38bc3eb3-b978-43c0-a2be-50eeda (Blood Derived Normal), aliquot 38bc3eb3-b978-43c0-a2be-50eeda_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d74ed287-4723-4af9-84ae-84ffd8c10046

The open-access MAF lists 53 somatic variants for this specimen: 35 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 15, In Frame Del 2, RNA 2, Frame Shift Del 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 192/429 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 413/648 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60917876; called by muse, mutect2, varscan2
- ABCC12 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 181/266 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs1429335721; called by muse, mutect2, varscan2
- CACNA1C | c.2693A>G p.N898S | Missense Mutation (SNP) | VAF 122/238 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100221572; called by muse, varscan2
- CNTN4 | c.2604A>C p.K868N | Missense Mutation (SNP) | VAF 99/522 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV100639857; called by muse, mutect2, varscan2
- GATB | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332583133, COSV56134483; called by muse, mutect2, varscan2
- HNF1A | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 243/987 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs757068809, CM002867, COSV57468225; called by muse, mutect2, varscan2
- IL17RA | c.2096A>G p.E699G | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs758860212; called by mutect2, varscan2
- KLKB1 | c.437G>C p.R146P | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV52997849; called by muse, mutect2, varscan2
- MICAL3 | c.3761C>T p.P1254L | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs570795967; called by muse, mutect2, varscan2
- NFATC2 | c.2117C>A p.P706H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV65354095; called by muse, mutect2, varscan2
- NXNL1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 80/692 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs757310322, COSV100111923; called by muse, mutect2, varscan2
- PLEKHA6 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs758641396; called by muse, mutect2, varscan2
- ABCC12 | c.2642C>A p.S881Y | Missense Mutation (SNP) | VAF 421/653 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCG8 | c.167T>A p.V56E | Missense Mutation (SNP) | VAF 175/628 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ANTXRL | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATF2 | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CDK12 | c.3085del p.A1029Lfs*28 | Frame Shift Del (DEL) | VAF 72/100 reads (72%) | called by mutect2, varscan2
- DSPP | c.815A>C p.D272A | Missense Mutation (SNP) | VAF 86/369 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- E2F8 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- ITGAD | c.2175C>G p.S725R | Missense Mutation (SNP) | VAF 75/984 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2
- ITPR2 | c.4020A>C p.E1340D | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MALRD1 | c.3434G>T p.G1145V | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MCAM | c.940C>A p.H314N | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MEGF11 | c.846G>C p.Q282H | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MUC5B | c.15259G>A p.D5087N | Missense Mutation (SNP) | VAF 190/574 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- MXRA5 | c.5012_5014del p.T1671del | In Frame Del (DEL) | VAF 104/198 reads (53%) | called by pindel, varscan2
- PAPPA | c.4035G>T p.M1345I | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- PHLDB3 | c.1387C>A p.Q463K | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPUSD2 | c.465_471del p.R156Wfs*69 | Frame Shift Del (DEL) | VAF 57/245 reads (23%) | called by mutect2, pindel, varscan2
- SEC16B | c.2536C>G p.P846A | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SH3YL1 | c.118_120del p.V40del | In Frame Del (DEL) | VAF 47/170 reads (28%) | called by mutect2, pindel, varscan2
- SNX15 | c.860C>G p.A287G | Missense Mutation (SNP) | VAF 106/292 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- SQOR | c.577A>C p.T193P | Missense Mutation (SNP) | VAF 131/410 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF804B | c.1863A>G p.I621M | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2
- ATG2B | c.2448G>A p.Q816= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs752610400; called by muse, mutect2, varscan2
- ATG9A | c.2199G>A p.R733= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV99522455; called by muse, mutect2, varscan2
- FIG4 | c.81T>A p.V27= | Silent (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- FMO1 | c.540T>C p.D180= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs778509179; called by muse, mutect2, varscan2
- GPR55 | c.84C>T p.I28= | Silent (SNP) | VAF 145/465 reads (31%) | called by muse, mutect2, varscan2
- NTNG2 | c.684C>A p.R228= | Silent (SNP) | VAF 219/711 reads (31%) | called by muse, mutect2, varscan2
- PPP1R3A | c.66T>C p.S22= | Silent (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- SNRPA1 | c.504A>G p.A168= | Silent (SNP) | VAF 55/202 reads (27%) | called by muse, mutect2, varscan2
- SPTBN5 | c.5724G>A p.G1908= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1184054038; called by muse, mutect2, varscan2
- TENT4B | c.2133C>T p.L711= (on ENST00000561678 / NM_001365323.2; = p.L696= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/220 reads (37%) | called by muse, mutect2, varscan2
- TPO | c.1083C>T p.R361= | Silent (SNP) | VAF 51/153 reads (33%) | called by muse, mutect2, varscan2
- TRMT2B | c.1428C>T p.G476= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as rs778406818, COSV58621447; called by muse, mutect2, varscan2
- TTN | c.24282T>C p.V8094= (on ENST00000591111; = p.V7167= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/236 reads (20%) | called by muse, mutect2, varscan2
- TYR | c.633T>C p.H211= | Silent (SNP) | VAF 67/209 reads (32%) | called by muse, mutect2, varscan2
- ZSCAN16 | c.90A>G p.Q30= | Silent (SNP) | VAF 73/189 reads (39%) | called by muse, mutect2, varscan2
- FAM205BP | n.1940G>A | RNA (SNP) | VAF 235/777 reads (30%) | called by muse, mutect2, varscan2
- MIR514A3 | n.59C>A | RNA (SNP) | VAF 50/481 reads (10%) | called by muse, mutect2, varscan2
- MS4A6A | c.-207A>G | 5'UTR (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
